Gene-level copy-number profile of tumor specimen C3N-02529-01 (profiled together with C3N-02529-02) from CPTAC case C3N-02529, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 79.5 years (29,049 days).
Specimen C3N-02529-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bebeaab2-08dd-480c-8165-76853c0963eb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02529-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/0e39afc9-2947-4dfd-b023-44184250635a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 12,697; copy number 2: 27,985; copy number 3: 9,332; copy number 4: 6,964; copy number 5: 902; copy number 7: 428; copy number 8: 13; copy number 9: 48.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:33,969,567–36,321,404, 21 genes (within-gene range 0–1): AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr11:50,409,042–54,725,816, 12 genes: AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,391 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–146,914,294, 111 genes, copy number 5 (broad region; genes not listed).
- chr3:78,597,239–79,767,998, 1 gene, copy number 7 (within-gene range 3–7): ROBO1.
- chr3:78,938,009–79,958,142, 4 genes, copy number 7: RN7SL751P, AC117461.1, MIR3923, HMGB1P38.
- chr8:2,045,046–2,838,823, 10 genes, copy number 5: MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1.
- chr8:59,455,885–62,144,769, 37 genes, copy number 5: RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1.
- chr8:78,268,637–78,558,503, 1 gene, copy number 5 (within-gene range 4–5): PKIA-AS1.
- chr8:78,516,340–90,687,863, 172 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:96,239,398–99,877,580, 53 genes, copy number 8–9 (within-gene range 4–9): MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2, CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5, SNORD3H, AP002982.1, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P, STK3, AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P, AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1, VPS13B, AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1.
- chr8:106,215,763–109,691,791, 35 genes, copy number 7: SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, HMGB1P46, ANGPT1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1.
- chr8:110,105,076–145,066,685, 520 genes, copy number 5–9 (broad region; genes not listed).
- chr9:61,190,003–61,627,683, 9 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr12:32,727,490–32,755,897, 1 gene, copy number 5 (within-gene range 2–5): YARS2.
- chr12:32,736,930–32,896,777, 4 genes, copy number 5 (within-gene range 2–5): AC084824.4, AC087588.2, PKP2, AC087588.1.
- chr14:31,244,761–31,488,039, 10 genes, copy number 5: Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33.
- chr14:32,202,045–32,837,684, 8 genes, copy number 7: RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2.
- chr14:49,552,633–50,416,461, 44 genes, copy number 5: RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1, AL359397.1.
- chr14:83,805,496–90,185,853, 71 genes, copy number 5 (broad region; genes not listed).
- chr17:37,924,415–41,397,608, 191 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:80,991,598–81,881,106, 63 genes, copy number 5 (broad region; genes not listed).
- chr21:33,164,809–33,359,864, 7 genes, copy number 5: LINC01548, IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1.
- chr21:34,787,801–36,701,564, 39 genes, copy number 7 (within-gene range 3–8): RUNX1, AP000331.1, AF015262.1, RPL34P3, EZH2P1, AF015720.1, MIR802, RPS20P1, PPP1R2P2, LINC01436, RPL23AP3, SETD4, RIMKLBP1, SETD4-AS1, RNU6-992P, AP000688.1, CBR1, AP000688.3, AP000688.2, MEMO1P1, CBR3-AS1, RPS9P1, CBR3, DOP1B, RPL3P1, SRSF9P1, AP000692.2, MORC3, AP000692.1, CHAF1B, ATP5MFP1, AP000695.1, AP000695.2, CLDN14, AP000695.3, PSMD4P1, AP000696.2, AP000696.1, AP000697.1.

Autosomal genes at a single copy (total copy number 1): 12,636. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
